Somatic mutation profile of tumor specimen 433c2eb6-560f-4387-93af-6c2e1a (aliquot 433c2eb6-560f-4387-93af-6c2e1a_D6_1) from CPTAC case 15BR003, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA.
Specimen 433c2eb6-560f-4387-93af-6c2e1a: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa541d14-f04b-4cdd-87d6-a1e9920c4bc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 3de9a97b-ec2d-4778-b7cd-f52fb2 (Blood Derived Normal), aliquot 3de9a97b-ec2d-4778-b7cd-f52fb2_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/969a21f4-9c5c-42e9-8098-b7f386bbc5d0

The open-access MAF lists 697 somatic variants for this specimen: 478 protein-altering or splice-affecting, 152 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 409, Silent 152, Nonsense Mutation 43, Intron 34, Splice Site 11, 3'UTR 10, RNA 9, Splice Region 8, 5'UTR 7, 5'Flank 5, Nonstop Mutation 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 74/188 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASPM | c.7894C>T p.Q2632* | Nonsense Mutation (SNP) | VAF 54/389 reads (14%) | catalogued as rs199422175, CM092389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.5622C>G p.F1874L | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV66069803; called by muse, mutect2
- ABCA13 | c.9260C>T p.S3087F | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV101446958, COSV71288299; called by muse, mutect2
- ABO | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 104/476 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs782738668; called by muse, mutect2, varscan2
- AC134980.2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs200194923, COSV100171580; called by muse, mutect2, varscan2
- ACER1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766132556, COSV56835399, COSV56836014; called by muse, mutect2, varscan2
- ACER3 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as rs898100069; called by muse, mutect2, varscan2
- AHNAK2 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV100318059; called by muse, mutect2, varscan2
- AKAP4 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62074559; called by muse, mutect2, varscan2
- ANKRD28 | c.1248-1G>C p.X416_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as COSV67519722; called by muse, mutect2
- ANKRD44 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs925366258, COSV56567963; called by muse, mutect2, varscan2
- ARHGAP25 | c.931G>A p.D311N (on ENST00000409202 / NM_001007231.3; = p.D303N on NM_014882.3) | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV54909433; called by muse, mutect2
- ARHGDIA | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs759174824, COSV53907818; called by muse, mutect2, varscan2
- ARHGEF12 | c.4171G>C p.E1391Q | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV100754907; called by muse, mutect2, varscan2
- ATAD2 | c.3020G>A p.R1007Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as rs1355271043; called by muse, mutect2, varscan2
- BHLHE41 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1394647498; called by muse, mutect2, varscan2
- BIN1 | c.630C>G p.I210M (on ENST00000316724 / NM_001320642.1; = p.I179M on NM_004305.4) | Missense Mutation (SNP) | VAF 144/953 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV99387340; called by muse, mutect2, varscan2
- BRD8 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV50146296; called by muse, mutect2, varscan2
- BRSK1 | c.1860C>G p.I620M | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV58668965; called by muse, mutect2, varscan2
- C12orf4 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as COSV99712749; called by muse, mutect2
- CACNG8 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs755214736; called by muse, mutect2, varscan2
- CAST | c.951+1G>A p.X317_splice (on ENST00000341926; = p.X400_splice on NM_001750.7 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 16/90 reads (18%) | catalogued as rs910995862; called by muse, mutect2, varscan2
- CCDC180 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.947); catalogued as COSV63832358; called by muse, mutect2, varscan2
- CCDC7 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.671); catalogued as rs1404570735; called by muse, mutect2, varscan2
- CCP110 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV66817577; called by muse, mutect2, varscan2
- CCSER1 | c.1927C>T p.Q643* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | catalogued as COSV104414426, COSV61458737; called by muse, mutect2
- CCT8L2 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV100742569; called by muse, mutect2
- CD19 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 156/978 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs754124868; called by muse, mutect2, varscan2
- CDC7 | c.956G>A p.R319K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV52311088, COSV99319675; called by muse, mutect2, varscan2
- CDH7 | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59890167; called by muse, mutect2
- CEP41 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781878740; called by muse, mutect2, varscan2
- CFAP99 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs780469921; called by muse, mutect2, varscan2
- CHERP | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.052); catalogued as COSV52222300; called by muse, mutect2, varscan2
- CLDN22 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV60109910; called by muse, mutect2
- CNTNAP1 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1378367385, COSV99226062; called by muse, mutect2
- COL4A2 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749501904, COSV64625447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 86/491 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs571932580; called by muse, mutect2, varscan2
- CSF1R | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as rs774962435; called by muse, mutect2, varscan2
- DACH2 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV64167677, COSV64188504; called by muse, mutect2
- DCAF12 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs1254161878, COSV100778403; called by muse, mutect2, varscan2
- DENND4B | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs748707602, COSV63408603; called by muse, mutect2, varscan2
- DIS3L | c.979G>C p.E327Q (on ENST00000319212 / NM_001143688.3; = p.E244Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1420208695; called by muse, mutect2, varscan2
- DIS3L2 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 59/315 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99805989; called by muse, mutect2, varscan2
- DNAJC2 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); catalogued as COSV104374580; called by muse, mutect2
- DOCK6 | c.6116G>C p.R2039T | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1158897262, COSV53921917; called by muse, mutect2, varscan2
- DOT1L | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 66/417 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); catalogued as rs571375214; called by muse, mutect2, varscan2
- DPEP3 | c.1233G>A p.V411= | Splice Region (SNP) | VAF 50/263 reads (19%) | catalogued as COSV99262928; called by muse, mutect2, varscan2
- DSCAM | c.3404G>A p.G1135E | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.575); catalogued as rs755182429; called by muse, mutect2, varscan2
- ECEL1 | c.1431C>G p.I477M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1344169798; called by muse, mutect2, varscan2
- EN1 | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 29/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54632585; called by muse, mutect2
- ENTPD8 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as rs556851035, COSV58162342; called by muse, mutect2, varscan2
- EPCAM | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55393270; called by muse, mutect2
- EVPL | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 27/284 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs779524512, COSV56909178, COSV56912874; called by muse, mutect2
- FANCC | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV56667769; called by muse, mutect2
- FAT1 | c.9841G>C p.D3281H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV71675159; called by muse, mutect2
- FLG | c.4870G>C p.E1624Q | Missense Mutation (SNP) | VAF 80/577 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.178); catalogued as rs771190348; called by muse, mutect2, varscan2
- FREM1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs573357415, COSV66517690, COSV66528172; called by muse, mutect2, varscan2
- FREM2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99040211; called by muse, mutect2, varscan2
- FTCD | c.423C>G p.I141M | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1458352047; called by muse, mutect2, varscan2
- GALNT17 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.363); catalogued as rs752472906, COSV61153980, COSV61188172; called by muse, mutect2, varscan2
- GBP1 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs775940254; called by muse, mutect2, varscan2
- GGA2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1299032288; called by muse, mutect2
- GPR31 | c.17G>T p.C6F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs201491639, COSV64761379; called by muse, mutect2, varscan2
- GRID2 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs367770083, COSV99940437; called by muse, mutect2, varscan2
- GRIK3 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 29/455 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as rs1277571708; called by muse, mutect2
- GRIN2B | c.4021G>C p.E1341Q | Missense Mutation (SNP) | VAF 35/459 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.707); catalogued as COSV101663191, COSV74206579; called by muse, mutect2
- GUCY2C | c.1805C>G p.S602* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV53790544; called by muse, mutect2, varscan2
- H3C4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV61911531, COSV61912198, COSV61912262; called by muse, mutect2, varscan2
- HDLBP | c.939del p.K314Rfs*28 | Frame Shift Del (DEL) | VAF 48/321 reads (15%) | catalogued as COSV60501393; called by mutect2, varscan2
- HDX | c.1795G>C p.E599Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs763341370; called by mutect2, varscan2
- HEATR1 | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV63980790, COSV63983016; called by muse, mutect2
- HEATR1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV63979518, COSV63979583; called by muse, mutect2, varscan2
- HELZ2 | c.2890C>T p.R964* (on ENST00000467148 / NM_001037335.2; = p.R395* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 69/504 reads (14%) | catalogued as rs747066534, COSV104426333; called by muse, mutect2, varscan2
- HLA-F | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.919); catalogued as COSV99035854; called by muse, mutect2, varscan2
- HTRA2 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 84/642 reads (13%) | catalogued as COSV51207439; called by muse, mutect2, varscan2
- IKBKE | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs948499703; called by muse, mutect2, varscan2
- IL17REL | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs773742457, COSV100377490; called by muse, mutect2, varscan2
- IL21R | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV61969850; called by muse, mutect2, varscan2
- ING1 | c.1098G>A p.M366I | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58167112; called by muse, mutect2, varscan2
- IRS1 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.825); catalogued as rs1289819083, COSV59335187; called by muse, mutect2
- ISYNA1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471957289; called by muse, mutect2, varscan2
- JPH1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60614344; called by muse, varscan2
- KAZN | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs1217076482, COSV101055780; called by muse, mutect2, varscan2
- KCNK1 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as rs1180402757; called by muse, mutect2, varscan2
- KEL | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 144/689 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as CM165862; called by mutect2, varscan2
- KHDRBS2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs774551671, COSV55464127; called by muse, mutect2, varscan2
- KIAA1671 | c.5104G>A p.D1702N | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223268418; called by muse, mutect2
- KIF21A | c.2578C>G p.Q860E (on ENST00000361418 / NM_001378440.1; = p.Q847E on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100735520; called by muse, mutect2
- KIF7 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 72/509 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101067736; called by muse, mutect2, varscan2
- KLHL41 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.099); catalogued as COSV52931678; called by muse, mutect2, varscan2
- KLRC1 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV100760718; called by muse, mutect2, varscan2
- KRTAP10-4 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 135/898 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1555923426, COSV59956024; called by muse, mutect2, varscan2
- LAMA2 | c.2629G>C p.G877R | Missense Mutation (SNP) | VAF 46/612 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV101370834; called by muse, mutect2
- LGALS2 | c.384C>G p.F128L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99312594; called by muse, mutect2
- LGALS2 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs1224780259; called by muse, mutect2
- LGI4 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs1326647337, COSV59533060; called by muse, mutect2, varscan2
- LHX9 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV61329506; called by muse, mutect2
- LRBA | c.6473C>T p.A2158V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100842153; called by muse, mutect2, varscan2
- LRFN5 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99982396; called by muse, mutect2, varscan2
- LRRFIP1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427670910; called by muse, mutect2, varscan2
- LUC7L2 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100722245; called by muse, mutect2, varscan2
- MACC1 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539566890; called by muse, mutect2, varscan2
- MAGT1 | c.617G>C p.R206P (on ENST00000618282 / NM_001367916.1; = p.R238P on NM_032121.5) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63781409; called by muse, mutect2, varscan2
- MAP1A | c.411C>G p.F137L | Missense Mutation (SNP) | VAF 55/362 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.364); catalogued as COSV55810953; called by muse, mutect2, varscan2
- MAP3K19 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100209064, COSV100209511, COSV59638494; called by muse, mutect2, varscan2
- MAPRE3 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.611); catalogued as COSV51869423, COSV99252002; called by muse, mutect2
- MAST1 | c.897C>A p.F299L | Missense Mutation (SNP) | VAF 27/324 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52246009; called by muse, mutect2
- MCM5 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs749855231; called by muse, mutect2, varscan2
- MED13 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.275); catalogued as COSV67265964; called by muse, mutect2
- MFSD11 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs369294744; called by muse, mutect2, varscan2
- MGST3 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 145/442 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV63321432; called by muse, mutect2, varscan2
- MINK1 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as rs746187948, COSV53417233; called by muse, mutect2, varscan2
- MROH2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1427712030, COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2, varscan2
- MTO1 | c.1750G>A p.D584N (on ENST00000370300 / NM_133645.3; = p.D559N on NM_012123.4) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV64772970; called by muse, mutect2, varscan2
- MYH3 | c.5749C>A p.Q1917K | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV56862347, COSV56865081; called by muse, mutect2
- NID2 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV99356026; called by muse, mutect2, varscan2
- NLRP9 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV60463748; called by muse, mutect2, varscan2
- NR2F2 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67684312; called by muse, mutect2, varscan2
- NRXN3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 42/704 reads (6%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.955); catalogued as COSV73584986; called by muse, mutect2
- NT5C3B | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99505025; called by muse, mutect2
- NUP205 | c.2983C>G p.L995V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV53656415; called by muse, mutect2, varscan2
- NUP210L | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs866883415, COSV55157580; called by muse, mutect2
- OPLAH | c.3832G>A p.V1278I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs782398287, COSV66298016; called by muse, mutect2, varscan2
- OR11G2 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62132627; called by muse, mutect2, varscan2
- OTX1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1458361030, COSV99246086; called by muse, mutect2, varscan2
- PALB2 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs786203747, COSV55166965, COSV55169270; ClinVar: uncertain significance; called by muse, mutect2
- PCLO | c.13215G>A p.M4405I | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.203); catalogued as COSV100431192; called by muse, mutect2, varscan2
- PCLO | c.12331G>A p.E4111K | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs770208151, COSV100435816; called by muse, mutect2, varscan2
- PDE4DIP | c.4522G>C p.D1508H | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.552); catalogued as rs782497552; called by muse, mutect2, varscan2
- PHF2 | c.1616C>A p.S539* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV63682632; called by muse, mutect2, varscan2
- PIGC | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.727); catalogued as rs1438694548; called by muse, mutect2
- PLK2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV57110119; called by muse, mutect2
- PPARA | c.1347G>C p.K449N | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs1313272105; called by muse, mutect2, varscan2
- PRKAA2 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64802519; called by muse, mutect2, varscan2
- PRMT9 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 47/229 reads (21%) | catalogued as rs1397695069, COSV59359385; called by muse, mutect2, varscan2
- PRRC2B | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.981); catalogued as rs776316595; called by muse, mutect2, varscan2
- PSMB9 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1334041696, COSV62755106; called by muse, mutect2, varscan2
- RB1CC1 | c.4298G>C p.R1433T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV99208798; called by muse, mutect2, varscan2
- RBBP6 | c.4582G>C p.D1528H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs770447240; called by mutect2, varscan2
- RELB | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as rs1190927240; called by muse, mutect2, varscan2
- REXO5 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.22); catalogued as rs371377608; called by muse, mutect2, varscan2
- RFXAP | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.4); catalogued as rs1290515755; called by muse, mutect2, varscan2
- RNF183 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV52907931; called by muse, mutect2, varscan2
- RRM2B | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as COSV52566137; called by muse, varscan2
- RSPH1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs1388033798; called by muse, mutect2
- RYR2 | c.6834G>C p.Q2278H | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1269962708, COSV63698992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1047565580, COSV51764485, COSV51765123; called by muse, mutect2, varscan2
- SALL3 | c.3562G>A p.D1188N | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.965); catalogued as COSV73305954; called by muse, mutect2
- SARM1 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1460394367, COSV50229288; called by muse, mutect2, varscan2
- SCN4A | c.2637G>C p.K879N | Missense Mutation (SNP) | VAF 78/318 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.499); catalogued as COSV71126041; called by muse, mutect2, varscan2
- SHANK1 | c.2809C>A p.P937T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as rs561443642; called by muse, mutect2, varscan2
- SLC17A9 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs369696432; called by muse, mutect2, varscan2
- SLC6A13 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.229); catalogued as COSV100569720; called by muse, mutect2, varscan2
- SMARCAL1 | c.2818A>G p.R940G | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs777965487; called by muse, mutect2, varscan2
- SMG5 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1313512285; called by muse, mutect2
- SMG8 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs1255915800, COSV99959037; called by muse, mutect2
- SNED1 | c.3788C>T p.S1263L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs777017962; called by muse, mutect2, varscan2
- SPAG17 | c.5667G>A p.T1889= | Splice Region (SNP) | VAF 29/162 reads (18%) | catalogued as rs771676007, COSV60455422, COSV60468559; called by muse, mutect2, varscan2
- SPATA31D1 | c.1068C>A p.F356L | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV61194116; called by mutect2, varscan2
- SPOP | c.353-1G>T p.X118_splice | Splice Site (SNP) | VAF 26/89 reads (29%) | catalogued as COSV61653435; called by muse, mutect2, varscan2
- TARS3 | c.2146-1G>A p.X716_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | catalogued as rs772841483, COSV100255014; called by muse, mutect2, varscan2
- TAT | c.168C>G p.I56M | Missense Mutation (SNP) | VAF 11/413 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV63532322, COSV63533341; called by muse, mutect2
- TGFBR2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs766473954, COSV55448773; called by muse, mutect2, varscan2
- TLX1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV64622382, COSV64622417; called by muse, mutect2
- TMPRSS13 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 164/773 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV70627222; called by muse, mutect2, varscan2
- TNFAIP1 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 26/890 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV50228528; called by muse, mutect2
- TRIM32 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 115/785 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as rs749146435; called by muse, mutect2, varscan2
- TRIM66 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55124766; called by muse, mutect2
- TSPEAR | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.146); catalogued as rs1281531743; called by muse, mutect2, varscan2
- TTI1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs201294118, COSV100989645; called by muse, mutect2, varscan2
- TTN | c.47354G>C p.R15785T (on ENST00000591111; = p.R8361T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/131 reads (8%) | PolyPhen possibly damaging (0.647); catalogued as COSV60016024; called by muse, mutect2
- UQCRC2 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99193356; called by muse, mutect2, varscan2
- USP53 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99917448; called by muse, mutect2
- VPS72 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63168144; called by muse, mutect2
- VWA7 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs767669981, COSV100991791; called by muse, mutect2, varscan2
- WHRN | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 146/878 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs760297351, COSV54327695; called by muse, mutect2, varscan2
- ZNF114 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as COSV100251894; called by muse, mutect2, varscan2
- ZNF12 | c.892G>A p.E298K (on ENST00000405858 / NM_016265.4; = p.E260K on NM_006956.3) | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs780833245, COSV100703834; called by muse, mutect2
- ZNF131 | c.1000G>C p.E334Q (on ENST00000509156 / NM_001330707.2; = p.E300Q on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.224); catalogued as COSV100185496; called by muse, mutect2, varscan2
- ZNF17 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 5/89 reads (6%) | catalogued as rs1454245585; called by muse, mutect2
- ZNF443 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.548); catalogued as COSV56890455; called by muse, mutect2, varscan2
- ZNF547 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs749189364; called by muse, mutect2
- ZNF850 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as rs1219544132; called by muse, mutect2, varscan2
- ZNF99 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV101233725; called by muse, mutect2, varscan2
- ABHD18 | c.700-1G>C p.X234_splice (on ENST00000398965 / NM_001039717.2; = p.X141_splice on NM_025097.2 and 10 other RefSeq transcripts) | Splice Site (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- AC069544.2 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AC092143.1 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 36/633 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACACA | c.6275-1G>C p.X2092_splice | Splice Site (SNP) | VAF 13/366 reads (4%) | called by muse, mutect2
- ACAT1 | c.334+1G>A p.X112_splice | Splice Site (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- ACOT6 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ADAM10 | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- ADAM21 | c.513G>C p.M171I | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAMTS14 | c.2276A>T p.Q759L | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.326); called by muse, mutect2
- ADAMTSL3 | c.2867C>G p.S956C | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGB | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AEBP2 | c.1196A>C p.D399A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- AKAP4 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ANAPC1 | c.3048G>A p.M1016I | Missense Mutation (SNP) | VAF 43/692 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2
- ANGEL1 | c.1324C>T p.L442F | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- ANKRD30A | c.1798+1_1798+2dup | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- ANO2 | c.1614C>G p.I538M (on ENST00000356134 / NM_001278597.3; = p.I542M on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.142); called by muse, mutect2
- ANO8 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 17/420 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); called by muse, mutect2
- AP4E1 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ASCC3 | c.4285G>A p.E1429K | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASPHD2 | c.873C>G p.I291M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ASPM | c.9862G>C p.E3288Q | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ASPM | c.5060C>T p.S1687L | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ASTN1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATG2B | c.185C>A p.S62* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- ATP1A4 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2
- B4GAT1 | c.736C>G p.Q246E | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2
- BCL2L14 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BHMG1 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2
- BIRC6 | c.12736C>T p.L4246F | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BMPR2 | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BSN | c.1205C>A p.S402* | Nonsense Mutation (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- BTN3A1 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C20orf194 | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- C3 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 22/568 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, mutect2
- C4orf47 | c.813G>C p.K271N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- C4orf54 | c.3855G>A p.M1285I | Missense Mutation (SNP) | VAF 30/620 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2
- CALR | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CATSPER2 | c.717+3G>A | Splice Region (SNP) | VAF 18/489 reads (4%) | called by muse, mutect2
- CCDC168 | c.11539C>G p.L3847V | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CCDC69 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CCDC77 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCIN | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2
- CDIP1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- CDK5RAP2 | c.2270C>G p.S757* | Nonsense Mutation (SNP) | VAF 41/289 reads (14%) | called by muse, mutect2
- CDR2L | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- CEACAM5 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CELSR1 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 28/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP70 | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- CHD5 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2
- CIR1 | c.1148G>A p.R383K | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLOCK | c.2401A>C p.I801L | Missense Mutation (SNP) | VAF 59/460 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.847); called by muse, varscan2
- CLRN3 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CMAS | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CMYA5 | c.8944G>C p.E2982Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CMYA5 | c.9088G>C p.E3030Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2
- CMYA5 | c.9715G>C p.E3239Q | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CNBP | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- CNOT3 | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 20/632 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL12A1 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- COL18A1 | c.3491C>G p.S1164C (on ENST00000359759 / NM_130444.3; = p.S929C on NM_030582.4) | Missense Mutation (SNP) | VAF 38/588 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.431); called by muse, mutect2
- COL28A1 | c.2947G>A p.D983N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CPE | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.98); called by muse, mutect2
- CUL4B | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CYP24A1 | c.29C>A p.S10* | Nonsense Mutation (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- DCTPP1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 12/328 reads (4%) | called by muse, mutect2
- DDX27 | c.1251G>C p.L417F | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DENND4A | c.1812C>G p.F604L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DENND4A | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- DGCR8 | c.2001G>C p.K667N | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DGKZ | c.3268G>A p.A1090T (on ENST00000454345 / NM_001105540.2; = p.A902T on NM_003646.4) | Missense Mutation (SNP) | VAF 31/354 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2
- DMBT1 | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- DNAH11 | c.11672G>C p.R3891T | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DNMT1 | c.2010C>A p.C670* | Nonsense Mutation (SNP) | VAF 26/782 reads (3%) | called by muse, mutect2
- DPP10 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- DRC7 | c.2148C>G p.I716M | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DSP | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DST | c.10458C>G p.F3486L | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DYNC1H1 | c.4906G>A p.D1636N | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EBF2 | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EDC4 | c.1098C>G p.F366L | Missense Mutation (SNP) | VAF 104/424 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ELAC1 | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- ELAPOR1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.303); called by muse, mutect2
- EPC2 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- ERCC4 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); called by mutect2, varscan2
- EXOC3L1 | c.1834G>C p.D612H | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FAM155A | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FANCM | c.2782C>T p.Q928* | Nonsense Mutation (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- FBN1 | c.4661G>C p.G1554A | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- FBXL4 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); called by muse, mutect2
- FBXO45 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- FCGR2B | c.817+3G>A | Splice Region (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- FGL2 | c.386G>C p.R129T | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- FILIP1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.04); called by mutect2, varscan2
- FILIP1L | c.3358C>T p.L1120F (on ENST00000354552 / NM_182909.3; = p.L880F on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- FLVCR1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- FOXL2 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by mutect2, varscan2
- FOXP3 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.239); called by muse, mutect2
- FOXS1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 69/380 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- FRAS1 | c.7479G>T p.E2493D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- FRMD1 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GATA3 | c.1200dup p.S401Vfs*106 | Frame Shift Ins (INS) | VAF 33/171 reads (19%) | called by mutect2, pindel, varscan2
- GNAS | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, varscan2
- GNG8 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GOLGA8S | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.34); called by muse, mutect2
- GON4L | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- GON4L | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- GRM5 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- H1-7 | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HAUS6 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HDAC9 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDC | c.788-3C>G | Splice Region (SNP) | VAF 27/346 reads (8%) | called by muse, mutect2
- HNRNPUL1 | c.1155G>C p.Q385H | Missense Mutation (SNP) | VAF 17/593 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- HPS3 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HPS4 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 16/513 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.275); called by muse, mutect2
- HSP90B1 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.075); called by muse, mutect2
- HTT | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- IFI44 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IFIT5 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2
- IGHMBP2 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 9/297 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- IGKV1-27 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.316); called by muse, mutect2
- IGSF9B | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- IL16 | c.3785C>G p.T1262S (on ENST00000302987 / NM_172217.5; = p.T561S on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- INSYN2A | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INVS | c.2423C>G p.S808C | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IPO7 | c.2791G>C p.D931H | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- IRF4 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KANK4 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- KCNJ1 | c.352C>G p.H118D | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- KCNT2 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2
- KDM4C | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- KIAA0232 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2
- KIF7 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 28/131 reads (21%) | called by muse, mutect2, varscan2
- KLK10 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2
- KRBA1 | c.466+3G>A | Splice Region (SNP) | VAF 115/524 reads (22%) | called by muse, mutect2, varscan2
- KRT83 | c.327G>T p.Q109H | Missense Mutation (SNP) | VAF 50/516 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KRTAP10-4 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 183/1248 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.281); called by muse, varscan2
- KRTAP5-10 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 67/265 reads (25%) | PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- L1CAM | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 21/497 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- L3HYPDH | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LBP | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); called by muse, mutect2
- LILRB4 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- LINS1 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LMNB2 | c.1200G>A p.E400= | Splice Region (SNP) | VAF 138/628 reads (22%) | called by muse, mutect2, varscan2
- LONP1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- LRRC8B | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 78/400 reads (20%) | called by muse, mutect2, varscan2
- LY6L | c.191-1G>A p.X64_splice | Splice Site (SNP) | VAF 38/163 reads (23%) | called by muse, mutect2, varscan2
- MAP1S | c.1423_1424del p.S475Rfs*18 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by pindel, varscan2
- MCM9 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.072); called by muse, mutect2
- MCUB | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- METTL2B | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- MTMR1 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MUC5B | c.5269C>G p.Q1757E | Missense Mutation (SNP) | VAF 85/418 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MUTYH | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 83/507 reads (16%) | called by muse, mutect2, varscan2
- MYH15 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYOC | c.1228A>G p.N410D | Missense Mutation (SNP) | VAF 136/869 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- NAT14 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NBEA | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NBPF1 | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 69/970 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.609); called by muse, varscan2
- NBPF9 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 36/473 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); called by muse, mutect2
- NCKAP1 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- NECTIN1 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 171/742 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEK1 | c.2849G>C p.G950A | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NID2 | c.3167G>A p.G1056E | Missense Mutation (SNP) | VAF 53/379 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR3C1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 13/300 reads (4%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.455); called by muse, mutect2
- NR3C1 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 20/506 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- NSD2 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2
- NSMCE4A | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- OR2T8 | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAX9 | c.1025G>C p.*342Sext*58 | Nonstop Mutation (SNP) | VAF 14/464 reads (3%) | called by muse, mutect2
- PCDHB15 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDHGA1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- PCDHGB7 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCGF1 | c.201C>G p.F67L | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PCLO | c.12869G>C p.R4290T | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- PCLO | c.12033G>C p.L4011F | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNT | c.4903G>A p.E1635K | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCNX1 | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2
- PER1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- PFKFB1 | c.800G>C p.R267T | Missense Mutation (SNP) | VAF 126/654 reads (19%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGM2L1 | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- PGM2L1 | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PHF12 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2
- PHTF1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGT | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIK3C2A | c.3699C>G p.I1233M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2G4E | c.1270G>C p.D424H | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); called by muse, mutect2
- PLEKHA6 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 34/566 reads (6%) | called by muse, mutect2
- PLXNB3 | c.2409G>C p.R803S | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- PNPO | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- POLR1A | c.3270G>C p.L1090F | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLR2B | c.3478C>T p.Q1160* | Nonsense Mutation (SNP) | VAF 11/180 reads (6%) | called by muse, mutect2
- PPIP5K1 | c.3411C>A p.S1137R (on ENST00000396923; = p.S1112R on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, varscan2
- PPM1K | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- PPP1R15A | c.614G>C p.R205T | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PRAMEF4 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRSS53 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRSS54 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 104/438 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- PTCD1 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 55/433 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- PUF60 | c.1657G>C p.D553H (on ENST00000526683 / NM_001362896.2; = p.D536H on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/378 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.235); called by mutect2, varscan2
- RAB3GAP1 | c.2025G>C p.Q675H | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RALGPS2 | c.1648C>G p.Q550E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- RBAK | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- RGPD8 | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RHOU | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- RPE65 | c.1317G>C p.L439F | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- RPL35 | c.371G>C p.*124Sext*6 | Nonstop Mutation (SNP) | VAF 32/138 reads (23%) | called by muse, mutect2, varscan2
- RPL5 | c.44G>C p.R15T | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- RPS6KA1 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 58/210 reads (28%) | called by muse, mutect2, varscan2
- RSF1 | c.3728G>T p.R1243I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RTL1 | c.3907G>C p.D1303H | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RUBCNL | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 75/402 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RYR1 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 137/815 reads (17%) | called by muse, mutect2, varscan2
- RYR1 | c.15001G>A p.E5001K | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- SACS | c.8513C>G p.S2838* | Nonsense Mutation (SNP) | VAF 46/334 reads (14%) | called by muse, mutect2, varscan2
- SBK3 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 38/209 reads (18%) | called by muse, mutect2, varscan2
- SCAF11 | c.1006C>G p.Q336E | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by mutect2, varscan2
- SCAF8 | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCD5 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SCP2D1-AS1 | n.216G>C | Splice Region (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2, varscan2
- SELENBP1 | c.534G>C p.E178D | Missense Mutation (SNP) | VAF 59/310 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SEPHS2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SFRP5 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SIGLEC8 | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- SIN3B | c.420C>G p.F140L | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIRT5 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SKI | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- SLC1A4 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SLC28A3 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC29A4 | c.72G>C p.M24I | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); called by muse, mutect2
- SLC3A2 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- SLC5A7 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SMC1A | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 78/514 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- SNAI1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SNCA | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SON | c.3424G>A p.E1142K | Missense Mutation (SNP) | VAF 23/381 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- SPATA31E1 | c.2821G>A p.D941N | Missense Mutation (SNP) | VAF 137/681 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SPTBN5 | c.5522G>A p.R1841K | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- SRGAP2 | c.1228G>A p.D410N (on ENST00000624873 / NM_001170637.4; = p.D411N on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by mutect2, varscan2
- STAC | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2
- STAC2 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STOML1 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- STOML1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 98/622 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STRADA | c.1210G>C p.E404Q (on ENST00000336174 / NM_001363786.1; = p.E367Q on NM_001003786.3) | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SUZ12 | c.1458G>C p.R486S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2
- SYNE1 | c.22114G>A p.E7372K (on ENST00000367255 / NM_182961.4; = p.E7301K on NM_033071.3) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SYNE1 | c.15634G>C p.E5212Q (on ENST00000367255 / NM_182961.4; = p.E5141Q on NM_033071.3) | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.218); called by muse, mutect2
- TBC1D2B | c.2021G>A p.W674* | Nonsense Mutation (SNP) | VAF 40/221 reads (18%) | called by muse, mutect2, varscan2
- TCHHL1 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2
- TGM4 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- THRSP | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 67/331 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TJP1 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMEM132A | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TOR1AIP1 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 34/333 reads (10%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); called by muse, mutect2
- TRAF3 | c.571-1G>C p.X191_splice | Splice Site (SNP) | VAF 48/458 reads (10%) | called by mutect2, varscan2
- TRAPPC2B | c.405G>C p.K135N | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TRAPPC3L | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRDC | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.009); called by muse, mutect2
- TRIM72 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- TRIOBP | c.5284C>T p.P1762S | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- TRPC1 | c.324T>A p.C108* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- TSSK3 | c.146-1G>A p.X49_splice | Splice Site (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- TTN | c.55333G>A p.E18445K (on ENST00000591111; = p.E11021K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- UBA2 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- UBASH3B | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBR1 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UBTFL1 | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 57/500 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- USP28 | c.2410G>T p.E804* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- UTP20 | c.2312-1G>C p.X771_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- VCAN | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- VCAN | c.7897G>C p.E2633Q | Missense Mutation (SNP) | VAF 35/476 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2
- VEZF1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.914); called by muse, mutect2
- VILL | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13B | c.11038G>C p.E3680Q | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2
- WDR20 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 20/658 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR25 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- WDR27 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- WIZ | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.345); called by muse, mutect2
- YARS2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); called by muse, mutect2
- ZAN | c.4835C>T p.S1612L | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2
- ZBTB4 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- ZDHHC4 | c.1034G>C p.*345Sext*7 | Nonstop Mutation (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- ZFHX3 | c.5932G>A p.E1978K | Missense Mutation (SNP) | VAF 22/421 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2
- ZGPAT | c.1202G>C p.R401T | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZIM2 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 100/525 reads (19%) | called by muse, mutect2, varscan2
- ZNF33B | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- ZNF354C | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 41/243 reads (17%) | called by muse, mutect2, varscan2
- ZNF460 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF574 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 30/406 reads (7%) | called by muse, mutect2
- ZNF705A | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2
- ZNF768 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 74/464 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZW10 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA2 | c.2671C>T p.L891= (on ENST00000614293; = p.L861= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/505 reads (4%) | called by muse, mutect2
- ACTG2 | c.252G>A p.E84= | Silent (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.1920G>A p.L640= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- AL441992.2 | c.1476C>T p.F492= | Silent (SNP) | VAF 59/285 reads (21%) | called by muse, mutect2, varscan2
- AMER1 | c.1029C>T p.S343= | Silent (SNP) | VAF 15/196 reads (8%) | catalogued as COSV100366646; called by muse, mutect2
- AMN1 | c.696G>A p.L232= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2
- ANKS1B | c.2493G>A p.L831= (on ENST00000547776 / NM_152788.4; = p.L57= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/367 reads (22%) | catalogued as COSV60365263; called by muse, mutect2, varscan2
- AP5M1 | c.261G>C p.L87= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as COSV55105977; called by muse, mutect2, varscan2
- ARHGAP39 | c.1716G>A p.Q572= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- ASIC4 | c.1416C>T p.I472= (on ENST00000347842 / NM_182847.3; = p.I491= on NM_018674.6) | Silent (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2, varscan2
- ASTN2 | c.2886G>A p.Q962= (on ENST00000313400 / NM_001365069.1; = p.Q911= on NM_014010.5) | Silent (SNP) | VAF 78/429 reads (18%) | called by muse, mutect2, varscan2
- ATAD1 | c.513G>A p.Q171= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs1481830456, COSV57756642; called by muse, mutect2, varscan2
- BEST1 | c.429C>A p.V143= | Silent (SNP) | VAF 38/224 reads (17%) | called by muse, mutect2, varscan2
- BMPR2 | c.2247G>A p.Q749= | Silent (SNP) | VAF 58/418 reads (14%) | called by muse, mutect2, varscan2
- BPIFB6 | c.4C>T p.L2= | Silent (SNP) | VAF 60/285 reads (21%) | catalogued as rs1347748515, COSV100848513; called by muse, mutect2, varscan2
- C1GALT1 | c.1078T>C p.L360= | Silent (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- C6orf89 | c.63G>A p.V21= (on ENST00000373685; = p.V28= on NM_152734.4) | Silent (SNP) | VAF 28/245 reads (11%) | called by muse, mutect2, varscan2
- C9orf153 | c.198C>T p.F66= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- CARMIL3 | c.1959G>A p.Q653= | Silent (SNP) | VAF 102/568 reads (18%) | catalogued as rs61732659, COSV57726338; called by muse, mutect2, varscan2
- CASK | c.1371G>A p.L457= | Silent (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- CCR10 | c.840G>A p.R280= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- CCR2 | c.732C>T p.V244= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as rs779353944, COSV52749091; called by muse, mutect2
- CELSR3 | c.567G>A p.R189= | Silent (SNP) | VAF 32/161 reads (20%) | catalogued as COSV50898863; called by muse, varscan2
- COL6A3 | c.3183C>T p.G1061= | Silent (SNP) | VAF 22/314 reads (7%) | called by muse, mutect2
- COL6A6 | c.3840C>T p.L1280= | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2
- CREB3L3 | c.1275G>A p.L425= | Silent (SNP) | VAF 67/376 reads (18%) | catalogued as rs773498032, COSV50183883; called by muse, mutect2, varscan2
- CYP11B2 | c.150G>C p.L50= | Silent (SNP) | VAF 44/938 reads (5%) | called by muse, mutect2
- DBX2 | c.765C>T p.I255= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- DDX10 | c.168C>T p.L56= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1397987678, COSV59434474; called by muse, mutect2
- DLG5 | c.2856C>G p.L952= | Silent (SNP) | VAF 66/354 reads (19%) | catalogued as COSV64946522; called by muse, varscan2
- DNAH11 | c.9615G>A p.L3205= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV60964434; called by muse, mutect2, varscan2
- DNAJC30 | c.345C>A p.L115= | Silent (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- EDC4 | c.1188C>T p.F396= | Silent (SNP) | VAF 61/288 reads (21%) | catalogued as rs758125973, COSV62767142, COSV62767992; called by muse, mutect2, varscan2
- EDC4 | c.2562G>A p.K854= | Silent (SNP) | VAF 42/208 reads (20%) | called by muse, mutect2, varscan2
- EEF1AKNMT | c.225G>C p.V75= | Silent (SNP) | VAF 38/477 reads (8%) | called by muse, mutect2
- EMC3 | c.477C>G p.L159= | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- FAM193B | c.1539G>A p.Q513= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs988721647; called by muse, mutect2
- FAM221A | c.24C>T p.L8= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1362559288, COSV61387468; called by muse, mutect2, varscan2
- FANCA | c.3450G>A p.L1150= | Silent (SNP) | VAF 24/322 reads (7%) | catalogued as rs1266179547; ClinVar: likely benign; called by muse, mutect2
- FAT2 | c.4674C>T p.L1558= | Silent (SNP) | VAF 18/572 reads (3%) | called by muse, mutect2
- FBL | c.498C>T p.L166= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as rs766314397; called by muse, mutect2
- FBXL7 | c.174G>A p.L58= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as COSV61644693; called by muse, mutect2, varscan2
- FBXO46 | c.1518C>A p.I506= | Silent (SNP) | VAF 64/386 reads (17%) | called by muse, mutect2, varscan2
- FCHO2 | c.1755C>T p.F585= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- FERMT3 | c.54G>A p.L18= | Silent (SNP) | VAF 41/288 reads (14%) | called by muse, mutect2, varscan2
- FFAR4 | c.345C>T p.F115= | Silent (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- FRMD5 | c.6G>A p.L2= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, varscan2
- GTPBP8 | c.132G>A p.L44= | Silent (SNP) | VAF 30/211 reads (14%) | catalogued as COSV55607064; called by muse, mutect2, varscan2
- HCAR2 | c.942G>A p.Q314= | Silent (SNP) | VAF 20/424 reads (5%) | called by muse, mutect2
- HK1 | c.621G>A p.V207= | Silent (SNP) | VAF 30/931 reads (3%) | called by muse, mutect2
- IL1RAP | c.1047G>A p.Q349= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV99300073; called by muse, mutect2, varscan2
- IMMT | c.1707C>G p.L569= | Silent (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- IMP4 | c.399C>T p.V133= | Silent (SNP) | VAF 20/484 reads (4%) | called by muse, mutect2
- IRS4 | c.750G>A p.L250= | Silent (SNP) | VAF 13/183 reads (7%) | called by muse, mutect2
- JUND | c.996C>T p.V332= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- KCNC4 | c.720C>T p.I240= | Silent (SNP) | VAF 65/273 reads (24%) | catalogued as rs768516084; called by muse, mutect2, varscan2
- KIAA1217 | c.2550G>A p.K850= | Silent (SNP) | VAF 92/678 reads (14%) | called by muse, mutect2
- KIF2C | c.555G>A p.V185= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- KIF7 | c.3879G>T p.L1293= | Silent (SNP) | VAF 49/277 reads (18%) | called by muse, mutect2, varscan2
- LAMA2 | c.2931C>T p.F977= | Silent (SNP) | VAF 86/392 reads (22%) | catalogued as rs750707755, COSV70342350; called by muse, mutect2, varscan2
- LILRA1 | c.39G>A p.L13= | Silent (SNP) | VAF 25/338 reads (7%) | catalogued as rs780169638; called by muse, mutect2
- LRIT3 | c.714C>G p.L238= | Silent (SNP) | VAF 68/383 reads (18%) | called by muse, mutect2, varscan2
- LRRC40 | c.96G>A p.L32= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV63939124; called by muse, mutect2, varscan2
- LRRC45 | c.504G>A p.L168= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs1247277415; called by muse, mutect2, varscan2
- LRRC8D | c.552C>T p.F184= | Silent (SNP) | VAF 43/241 reads (18%) | called by muse, mutect2, varscan2
- LRRTM3 | c.1191G>A p.P397= | Silent (SNP) | VAF 13/232 reads (6%) | catalogued as rs1339003025, COSV63660750; called by muse, mutect2
- MADCAM1 | c.1077G>A p.L359= | Silent (SNP) | VAF 45/302 reads (15%) | catalogued as COSV99298815; called by muse, mutect2, varscan2
- MAGI2 | c.3954G>C p.A1318= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV100836657; called by muse, mutect2, varscan2
- MCM2 | c.1599C>G p.L533= | Silent (SNP) | VAF 41/781 reads (5%) | catalogued as rs1253141846, COSV54032769; called by muse, mutect2
- MICAL2 | c.2382G>A p.K794= | Silent (SNP) | VAF 34/166 reads (20%) | catalogued as rs771726461; called by muse, mutect2, varscan2
- MTOR | c.657C>G p.L219= | Silent (SNP) | VAF 26/304 reads (9%) | called by muse, mutect2
- MTR | c.3246C>G p.L1082= | Silent (SNP) | VAF 25/997 reads (3%) | called by muse, mutect2
- MUC2 | c.807G>A p.V269= | Silent (SNP) | VAF 50/274 reads (18%) | called by muse, mutect2, varscan2
- NCBP2 | c.180C>T p.F60= | Silent (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- NEU1 | c.687C>T p.F229= | Silent (SNP) | VAF 21/618 reads (3%) | called by muse, mutect2
- NNT | c.657C>T p.I219= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- NOTCH1 | c.2790C>T p.F930= | Silent (SNP) | VAF 28/1055 reads (3%) | called by muse, mutect2
- NPPA | c.345G>A p.L115= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- NUP210L | c.282C>T p.L94= | Silent (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- OR5D16 | c.880C>T p.L294= | Silent (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- OSBPL5 | c.1785C>T p.V595= | Silent (SNP) | VAF 91/497 reads (18%) | catalogued as rs1262418249; called by muse, mutect2, varscan2
- P3H4 | c.162G>A p.E54= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- PAK2 | c.321G>A p.Q107= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs761898736; called by muse, mutect2, varscan2
- PDCD6IP | c.195C>T p.L65= | Silent (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- PDZD2 | c.6621G>C p.S2207= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as rs138558075; called by muse, mutect2, varscan2
- PDZRN3 | c.2727G>A p.L909= | Silent (SNP) | VAF 56/393 reads (14%) | catalogued as rs768239993; called by muse, mutect2, varscan2
- PFKFB3 | c.867G>A p.Q289= | Silent (SNP) | VAF 36/177 reads (20%) | called by muse, mutect2, varscan2
- PFKP | c.2271C>G p.L757= | Silent (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- PLXNA3 | c.1401C>G p.L467= | Silent (SNP) | VAF 89/561 reads (16%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4638C>G p.P1546= | Silent (SNP) | VAF 13/196 reads (7%) | catalogued as COSV58121963; called by muse, mutect2
- POTEA | c.183C>T p.V61= | Silent (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- PPIAL4G | c.264C>T p.L88= | Silent (SNP) | VAF 40/684 reads (6%) | called by muse, mutect2
- PPP1R12A | c.18G>A p.A6= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1438676758; called by muse, mutect2
- PRDM13 | c.564C>T p.L188= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs765425047; called by muse, varscan2
- PROX1 | c.780C>A p.I260= | Silent (SNP) | VAF 38/195 reads (19%) | called by muse, mutect2, varscan2
- PRSS53 | c.261G>A p.L87= | Silent (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- PSPC1 | c.213C>G p.L71= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- RASGEF1C | c.657C>A p.I219= | Silent (SNP) | VAF 41/244 reads (17%) | called by muse, mutect2, varscan2
- RGS14 | c.1560G>A p.L520= | Silent (SNP) | VAF 36/339 reads (11%) | called by muse, mutect2, varscan2
- RHOA | c.66C>G p.L22= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV101371140; called by muse, mutect2, varscan2
- SAMD9 | c.1140C>T p.F380= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV66073958; called by muse, mutect2, varscan2
- SASH1 | c.2460G>A p.R820= | Silent (SNP) | VAF 44/275 reads (16%) | called by muse, mutect2, varscan2
- SEMA4A | c.822C>T p.G274= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as rs761522614; called by muse, mutect2, varscan2
- SENP2 | c.1749C>A p.I583= | Silent (SNP) | VAF 26/257 reads (10%) | called by muse, mutect2, varscan2
- SH2D1A | c.33C>T p.I11= | Silent (SNP) | VAF 134/822 reads (16%) | catalogued as COSV100758289; called by muse, mutect2, varscan2
- SHOC2 | c.444C>G p.L148= | Silent (SNP) | VAF 61/413 reads (15%) | called by muse, mutect2, varscan2
- SLC35C2 | c.114G>A p.L38= | Silent (SNP) | VAF 42/230 reads (18%) | catalogued as rs775026863, COSV54756156; called by muse, mutect2, varscan2
- SLC35E4 | c.834C>T p.L278= | Silent (SNP) | VAF 27/366 reads (7%) | called by muse, mutect2
- SLC37A2 | c.300C>T p.I100= | Silent (SNP) | VAF 22/179 reads (12%) | catalogued as rs377738912; called by muse, mutect2
- SLC8A2 | c.2643C>T p.I881= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1416923803; called by muse, mutect2, varscan2
- SLC9A1 | c.2130G>A p.P710= | Silent (SNP) | VAF 35/215 reads (16%) | catalogued as rs762655180; called by muse, mutect2, varscan2
- SLC9A1 | c.2007G>A p.R669= | Silent (SNP) | VAF 79/387 reads (20%) | catalogued as rs1478014693; called by muse, mutect2, varscan2
- SORCS1 | c.216C>T p.L72= | Silent (SNP) | VAF 28/183 reads (15%) | catalogued as rs775319854; called by muse, mutect2, varscan2
- SPEN | c.6411G>A p.L2137= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs1211781929, COSV65360458; called by muse, mutect2
- SPIN2A | c.723C>T p.I241= | Silent (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- SPNS2 | c.1593C>T p.A531= | Silent (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- SRGAP1 | c.1464G>A p.Q488= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- SRPX2 | c.954C>T p.I318= | Silent (SNP) | VAF 20/608 reads (3%) | called by muse, mutect2
- SUCLG1 | c.63C>A p.L21= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs982734922, COSV67265520, COSV67265626; called by muse, mutect2
- SVOP | c.1377C>T p.L459= | Silent (SNP) | VAF 30/174 reads (17%) | catalogued as rs376465518; called by muse, mutect2, varscan2
- SWI5 | c.168C>A p.L56= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as COSV60791980; called by muse, mutect2, varscan2
- SYT9 | c.957C>T p.I319= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs767940383; called by muse, mutect2, varscan2
- TAP2 | c.456C>T p.L152= | Silent (SNP) | VAF 17/560 reads (3%) | called by muse, mutect2
- TAS1R3 | c.1014G>A p.V338= | Silent (SNP) | VAF 52/834 reads (6%) | catalogued as COSV59562181; called by muse, mutect2
- TBC1D2B | c.2751C>T p.I917= (on ENST00000300584 / NM_144572.1; = p.S900F on NM_015079.6) | Silent (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- TECPR1 | c.294G>C p.V98= | Silent (SNP) | VAF 22/475 reads (5%) | called by muse, mutect2
- TG | c.2925C>G p.L975= | Silent (SNP) | VAF 16/519 reads (3%) | called by muse, mutect2
- THBS2 | c.81C>T p.F27= | Silent (SNP) | VAF 38/188 reads (20%) | catalogued as rs766797702; called by muse, mutect2, varscan2
- THSD4 | c.777C>G p.L259= | Silent (SNP) | VAF 85/473 reads (18%) | called by muse, mutect2, varscan2
- TLE2 | c.2031G>A p.L677= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs1411620426; called by muse, mutect2
- TMC8 | c.621C>T p.L207= | Silent (SNP) | VAF 52/667 reads (8%) | catalogued as rs767898209; called by muse, mutect2
- TMEM214 | c.393G>A p.Q131= | Silent (SNP) | VAF 44/274 reads (16%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.264G>C p.L88= | Silent (SNP) | VAF 48/481 reads (10%) | catalogued as COSV52300103; called by muse, mutect2, varscan2
- TREH | c.936C>G p.L312= | Silent (SNP) | VAF 39/262 reads (15%) | catalogued as rs782478622; called by muse, mutect2, varscan2
- TRIM25 | c.1308C>G p.L436= | Silent (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- TRIM50 | c.54C>T p.I18= | Silent (SNP) | VAF 64/422 reads (15%) | called by muse, mutect2, varscan2
- TRIM68 | c.1143G>A p.R381= | Silent (SNP) | VAF 88/439 reads (20%) | called by muse, mutect2, varscan2
- TSR1 | c.2193G>A p.L731= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV100027243, COSV100027244; called by muse, mutect2
- TUBA1B | c.1116G>A p.Q372= | Silent (SNP) | VAF 62/1006 reads (6%) | catalogued as rs747103922; called by muse, mutect2
- USP4 | c.504G>A p.E168= | Silent (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- VAX1 | c.63C>G p.V21= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- VPS13A | c.42C>T p.F14= | Silent (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- VSIG10 | c.627G>A p.K209= | Silent (SNP) | VAF 70/333 reads (21%) | called by muse, mutect2, varscan2
- XKR3 | c.663C>T p.I221= | Silent (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
- XRCC6 | c.843C>G p.L281= | Silent (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- ZAN | c.3528C>T p.G1176= | Silent (SNP) | VAF 67/478 reads (14%) | catalogued as rs377076232; called by muse, mutect2, varscan2
- ZBP1 | c.1026C>T p.I342= | Silent (SNP) | VAF 20/411 reads (5%) | called by muse, mutect2
- ZNF142 | c.1629C>T p.F543= (on ENST00000411696 / NM_001379660.1; = p.F343= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 136/662 reads (21%) | called by muse, varscan2
- ZNF280A | c.879G>A p.K293= | Silent (SNP) | VAF 30/190 reads (16%) | called by muse, mutect2, varscan2
- ZNF609 | c.552G>A p.G184= | Silent (SNP) | VAF 18/235 reads (8%) | catalogued as rs910867827; called by muse, mutect2
- ZNF649 | c.747C>G p.L249= | Silent (SNP) | VAF 49/478 reads (10%) | called by mutect2, varscan2
- ZSCAN29 | c.1542C>T p.V514= | Silent (SNP) | VAF 32/453 reads (7%) | called by muse, mutect2
- AC024940.1 | n.245C>G | RNA (SNP) | VAF 15/238 reads (6%) | called by muse, mutect2
- ADAM10 | c.207-8864G>A | Intron (SNP) | VAF 10/233 reads (4%) | called by muse, mutect2
- AP1G2 | c.1287+20G>A | Intron (SNP) | VAF 83/540 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.989-97C>T | Intron (SNP) | VAF 105/616 reads (17%) | catalogued as COSV99986073; called by muse, mutect2, varscan2
- ASTN1 | c.1120+269C>G | Intron (SNP) | VAF 7/138 reads (5%) | catalogued as COSV99920858; called by muse, mutect2
- C3P1 | n.2610G>A | RNA (SNP) | VAF 38/238 reads (16%) | catalogued as rs1225159264; called by muse, mutect2, varscan2
- CDKN2C | c.-11-35G>C | Intron (SNP) | VAF 10/168 reads (6%) | catalogued as COSV99396032; called by muse, mutect2
- CEP170 | c.*296C>G | 3'UTR (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- CETN3 | c.461-2431A>G | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2, varscan2
- CFLAR | c.1305-782C>T | Intron (SNP) | VAF 16/184 reads (9%) | catalogued as rs779872106; called by muse, mutect2
- CHD5 | c.*8C>T | 3'UTR (SNP) | VAF 13/269 reads (5%) | catalogued as rs1381298696; called by muse, mutect2
- CLSTN3 | c.2528-790C>G | Intron (SNP) | VAF 39/361 reads (11%) | called by muse, mutect2, varscan2
- COILP1 | n.167C>G | RNA (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- COMMD3 | c.316-15C>G | Intron (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65741G>A | Intron (SNP) | VAF 42/524 reads (8%) | called by muse, mutect2
- DNAH8 | chr6:38722852 G>C | 5'Flank (SNP) | VAF 28/93 reads (30%) | catalogued as rs757017842; called by muse, mutect2, varscan2
- E4F1 | c.1057-19C>G | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- ENAH | c.803-160C>T | Intron (SNP) | VAF 52/335 reads (16%) | called by muse, mutect2, varscan2
- EVC | c.1563+1727G>A | Intron (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- FGF20 | c.-2C>A | 5'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, varscan2
- G6PC3 | c.*47C>T | 3'UTR (SNP) | VAF 96/546 reads (18%) | catalogued as rs1189544009; called by muse, mutect2, varscan2
- HSH2D | c.215+122G>C | Intron (SNP) | VAF 16/288 reads (6%) | called by muse, mutect2
- IK | chr5:140647766 C>T | 5'Flank (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- IL18 | c.92-19G>A | Intron (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- IL36B | c.261+883C>A | Intron (SNP) | VAF 26/215 reads (12%) | called by muse, mutect2, varscan2
- KIF7 | c.329-92C>T | Intron (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- KIRREL1 | c.*1574C>A | 3'UTR (SNP) | VAF 26/826 reads (3%) | called by muse, mutect2
- KLHL22 | c.-34+2605C>T | Intron (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
- L1CAM | c.3457+43G>C | Intron (SNP) | VAF 28/451 reads (6%) | called by muse, mutect2
- LINC01591 | n.281C>T | RNA (SNP) | VAF 63/432 reads (15%) | called by muse, mutect2, varscan2
- LITAF | chr16:11547973 C>T | 3'Flank (SNP) | VAF 50/335 reads (15%) | called by muse, mutect2, varscan2
- MCRIP1 | c.-48-1821G>A | Intron (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- MIR9-2 | n.37G>C | RNA (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+5131G>C | Intron (SNP) | VAF 14/261 reads (5%) | catalogued as COSV57931503; called by muse, mutect2
- MPRIP | c.2164-3880G>A | Intron (SNP) | VAF 11/215 reads (5%) | catalogued as rs1470397992; called by muse, mutect2
- MTHFR | c.475+27C>T | Intron (SNP) | VAF 30/362 reads (8%) | called by muse, mutect2
- NDE1 | c.1030+2906C>T | Intron (SNP) | VAF 11/106 reads (10%) | catalogued as rs1409994146; called by muse, mutect2, varscan2
- NDUFC2-KCTD14 | c.311-21444G>A | Intron (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- NFIX | c.28-36C>T | Intron (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- NXF5 | n.994G>A | RNA (SNP) | VAF 49/371 reads (13%) | catalogued as rs745648820, COSV53791295, COSV99534107; called by muse, mutect2, varscan2
- PATZ1 | chr22:31347405 G>C | 5'Flank (SNP) | VAF 19/144 reads (13%) | catalogued as rs1193228579; called by muse, mutect2, varscan2
- PGR | c.2646+19C>G | Intron (SNP) | VAF 34/132 reads (26%) | called by muse, mutect2, varscan2
- PIN1 | c.*167G>A | 3'UTR (SNP) | VAF 10/185 reads (5%) | catalogued as rs1271392007; called by muse, mutect2
- PPP1R16A | c.-40C>G | 5'UTR (SNP) | VAF 21/409 reads (5%) | catalogued as rs1278053114; called by muse, mutect2
- PRR14 | c.-80C>T | 5'UTR (SNP) | VAF 10/207 reads (5%) | called by muse, mutect2
- PRSS53 | c.-17G>A | 5'UTR (SNP) | VAF 78/361 reads (22%) | called by muse, mutect2, varscan2
- PSMD1 | c.-13G>A | 5'UTR (SNP) | VAF 9/39 reads (23%) | catalogued as rs1469497483; called by muse, mutect2, varscan2
- RAPGEF6 | c.3746-2401C>G | Intron (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- SBK3 | c.*99G>A | 3'UTR (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- SERPINA3 | chr14:94612383 G>C | 5'Flank (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- SETBP1 | c.540+7353C>G | Intron (SNP) | VAF 16/120 reads (13%) | catalogued as COSV56330151; called by muse, mutect2
- SLC6A10P | n.3171C>G | RNA (SNP) | VAF 31/662 reads (5%) | called by muse, mutect2
- SLC6A13 | c.479-286G>C | Intron (SNP) | VAF 40/396 reads (10%) | called by muse, mutect2
- SLC6A9 | chr1:43995591 C>G | 3'Flank (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- SLC9A7P1 | n.325C>G | RNA (SNP) | VAF 24/454 reads (5%) | called by muse, mutect2
- SNORD116-26 | n.44G>A | RNA (SNP) | VAF 23/184 reads (13%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-26648C>T | Intron (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- SPINT1 | c.-30C>T | 5'UTR (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- SWI5 | c.-12C>T | 5'UTR (SNP) | VAF 41/229 reads (18%) | catalogued as COSV60792957; called by muse, mutect2, varscan2
- USP22 | c.*15G>A | 3'UTR (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- VAMP7 | c.*98G>A | 3'UTR (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
- WDFY1 | c.*6G>C | 3'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2
- YAF2 | c.152+27028G>A | Intron (SNP) | VAF 30/153 reads (20%) | catalogued as rs1444487933, COSV59891344; called by muse, mutect2, varscan2
- YPEL3 | c.270+48C>T | Intron (SNP) | VAF 29/151 reads (19%) | catalogued as rs1567345704, COSV99661643; called by muse, mutect2, varscan2
- Z97634.1 | n.521+3597G>A | Intron (SNP) | VAF 36/200 reads (18%) | called by muse, mutect2
- ZNF559 | chr19:9324243 C>A | 5'Flank (SNP) | VAF 52/232 reads (22%) | called by muse, mutect2, varscan2
- ZNF646 | c.*1263C>T | 3'UTR (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
